Gene-level copy-number profile of tumor specimen MP2PRT-PASRME-TMP1-A from MP2PRT case MP2PRT-PASRME, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,900 days).
Specimen MP2PRT-PASRME-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 55530677-3eb6-437c-89f2-e6f91408b74a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PASRME-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,730 have no estimate.
https://portal.gdc.cancer.gov/files/edac0aa8-7744-497e-b9c5-5cd0f38bdf81

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 600; copy number 1: 3,778; copy number 2: 52,840; copy number 3: 1,675.

Homozygous deletions (total copy number 0; autosomes only): 271 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,234,912, 40 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29.
- chr2:89,968,867–89,990,221, 3 genes: IGKV1D-27, IGKV2D-26, IGKV3D-25.
- chr2:90,121,786–90,173,414, 3 genes: IGKV2D-14, IGKV1D-13, IGKV3D-11.
- chr2:90,220,727–90,221,384, 1 gene: IGKV1D-8.
- chr7:38,239,580–38,378,804, 23 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1.
- chr7:142,636,924–142,802,748, 29 genes: TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBC2.
- chr14:22,438,547–22,450,139, 4 genes (within-gene range 0–2): TRDD1, TRDD2, TRDD3, TRDJ1.
- chr14:105,672,308–106,715,181, 168 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,434. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
